Somatic mutation profile of tumor specimen TCGA-EY-A72D-01A (aliquot TCGA-EY-A72D-01A-12D-A34Q-09) from TCGA case TCGA-EY-A72D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 87.1 years (31,818 days).
Specimen TCGA-EY-A72D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e10813a-4dfc-4780-9853-8121254a27fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A72D-10A (Blood Derived Normal), aliquot TCGA-EY-A72D-10A-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/249b61a5-6c59-4cce-ad44-f043976a0122

The open-access MAF lists 57 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 3, RNA 2, Frame Shift Del 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 39/50 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4130C>T p.T1377M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs397516201, CM034558, COSV62518766; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 22/37 reads (59%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.6710A>T p.D2237V | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101204225; called by muse, mutect2, varscan2
- CACNA2D1 | c.116A>C p.K39T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV62390922; called by muse, mutect2, varscan2
- CSMD2 | c.9584C>T p.T3195M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs180811686; called by muse, mutect2, varscan2
- EPPK1 | c.6610C>T p.R2204W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370047268; called by muse, varscan2
- IL21R | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs771092403, COSV100560105; called by muse, mutect2, varscan2
- ITPR2 | c.7970T>G p.M2657R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV101189981; called by muse, mutect2, varscan2
- ITPRID1 | c.2992G>A p.G998R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100086376, COSV100086409; called by muse, mutect2, varscan2
- KHDRBS2 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99832027; called by muse, mutect2, varscan2
- KIF26A | c.1095C>A p.N365K | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV100181132; called by muse, mutect2, varscan2
- LAMA1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200626690; called by muse, mutect2, varscan2
- LGALS13 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs748246666, COSV55680217; called by muse, mutect2, varscan2
- LRRC4B | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV65350238; called by muse, mutect2
- MAGEE2 | c.1112T>C p.V371A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100973080; called by muse, mutect2, varscan2
- MANEA | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as rs756272049, COSV100721528; called by muse, mutect2, varscan2
- MAP3K15 | c.3887C>T p.A1296V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs756039907, COSV58835321; called by muse, mutect2, varscan2
- MBD3L2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs755922371, COSV100421452; called by muse, mutect2, varscan2
- MIA2 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as COSV99696775; called by muse, mutect2, varscan2
- MORF4L1 | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV100489122; called by muse, mutect2, varscan2
- MRGPRX1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100245986, COSV57106122; called by muse, mutect2, varscan2
- OCRL | c.2519T>A p.M840K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV100843443; called by muse, mutect2, varscan2
- OR8A1 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV99420571; called by muse, mutect2
- OTUB2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99180175; called by muse, mutect2
- PPP6R3 | c.1306C>T p.R436* (on ENST00000393800 / NM_001352375.2; = p.R385* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as rs751229732, COSV99676428; called by muse, mutect2, varscan2
- PRDM5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761027478, CM1512082, COSV53360890; called by muse, mutect2, varscan2
- PRDM9 | c.2431C>T p.R811W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs775272924, COSV57012158; called by muse, varscan2
- RGS13 | c.34T>G p.C12G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101232230; called by muse, mutect2, varscan2
- RPF2 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs575146968, COSV100923281; called by muse, mutect2, varscan2
- RYR2 | c.9433A>T p.S3145C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs771253050, COSV100770110, COSV63669042; called by muse, mutect2, varscan2
- SLC16A10 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs747108048, COSV100920876; called by muse, varscan2
- SLC24A3 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs748877701, COSV100041127, COSV100042783; called by muse, mutect2, varscan2
- TAF1 | c.3482G>T p.R1161L (on ENST00000373790 / NM_138923.4; = p.R1182L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52111361, COSV99335726; called by muse, mutect2, varscan2
- TAS2R16 | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99972248; called by muse, mutect2, varscan2
- TRPV5 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99520531; called by muse, mutect2, varscan2
- TTN | c.3907C>A p.L1303I (on ENST00000591111; = p.L1257I on NM_003319.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | PolyPhen benign (0.048); catalogued as COSV60031016; called by muse, mutect2, varscan2
- UQCRQ | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 23/23 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99737359; called by muse, mutect2, varscan2
- CHD6 | c.3419_3423del p.Y1140Cfs*5 | Frame Shift Del (DEL) | VAF 30/59 reads (51%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.8672_8677del p.E2891_R2893delinsG | In Frame Del (DEL) | VAF 13/18 reads (72%) | called by mutect2, varscan2
- TRAV4 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAN | c.2916C>T p.D972= | Silent (SNP) | VAF 62/74 reads (84%) | catalogued as rs750073964, COSV100718087; called by muse, mutect2, varscan2
- ALKBH3 | c.615T>C p.A205= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100236303; called by muse, mutect2, varscan2
- ATP1A3 | c.2574G>C p.G858= (on ENST00000545399 / NM_001256214.2; = p.G845= on NM_152296.5) | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV100132252; called by muse, mutect2, varscan2
- CAND2 | c.132C>T p.D44= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99929120; called by muse, mutect2, varscan2
- CHIA | c.249G>C p.L83= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100588666, COSV58477377; called by muse, mutect2
- CYC1 | c.390G>A p.V130= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV100010396; called by muse, mutect2, varscan2
- DGKG | c.1152C>T p.D384= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs770406720, COSV53974153; called by muse, mutect2, varscan2
- GABRA6 | c.234G>T p.T78= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV50877988, COSV99194495; called by muse, mutect2, varscan2
- GATA3 | c.507C>T p.T169= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1239082325, COSV100650999, COSV60521419; called by muse, mutect2, varscan2
- OOEP | c.84A>T p.P28= | Silent (SNP) | VAF 39/59 reads (66%) | catalogued as COSV100949826; called by muse, mutect2, varscan2
- PKNOX2 | c.1152G>T p.V384= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100020819; called by muse, mutect2, varscan2
- PLPP4 | c.564C>T p.C188= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs747534051, COSV64829035; called by muse, mutect2, varscan2
- UEVLD | c.627G>A p.R209= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100293178; called by muse, mutect2, varscan2
- DCHS2 | n.1716G>A | RNA (SNP) | VAF 49/60 reads (82%) | catalogued as rs74422312, COSV59721266; called by muse, mutect2, varscan2
- TMEM99 | n.476G>T | RNA (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100054074; called by muse, mutect2, varscan2
- XPO5 | c.*1152_*1153del | 3'UTR (DEL) | VAF 30/46 reads (65%) | catalogued as rs765625820; called by mutect2, pindel, varscan2
